Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KQ, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KQ-01A (Primary Tumor).

Procedure: R adrenalectomy

Gross description: 7.5 x 7.5 x 5cm, 153g

Diagnosis: adrenocortical carcinoma

Reference Pathology:

Diagnosis: adrenocortical carcinoma, KI67 2-3%, borderline malignant, but classified as malignant

Weiss score: 3

Hough score: 1.31

Van Slooten score: 8

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site (R) Adrenal Gland, cortex
C74.2

gwd 2/6/13

ICDAA Discrepancy		/

Source: NCI Genomic Data Commons file 6f801486-85bd-4e7a-a0da-dc8a1aa74277 (TCGA-OR-A5KQ.7ED6314A-1343-47D5-A40D-4B53FA3D33DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).